Surgical pathology report (de-identified scan), TCGA case TCGA-H2-A3RI, project TCGA-THCA (Thyroid Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-H2-A3RI-01A (Primary Tumor).

6 -

Final Surgical Pathology Report

Procedure:

Diagnosis

A. Thyroid, total thyroidectomy:

Papillary carcinoma (2.7 cm) with focal extension into the perithyroidal fat.

Margin of resection is free of carcinoma.

3 perithyroidal lymph nodes negative for metastatic carcinoma (0/3).

B. Lymph nodes, central cervical, resection:

2 lymph nodes negative for metastatic carcinoma (0/2).

Microscopic Description:

Histologic type: Papillary carcinoma

Primary tumor (pT): The tumor measures maximally 2.7 cm and focally extends into the perithyroidal fat.

(pT3).

Margins of resection: Negative

Vascular invasion: Negative

Regional lymph nodes (pN): 3 perithyroidal lymph nodes and two central cervical lymph nodes

are negative for

metastatic carcinoma (pN0).

Distant metastasis (pM): pMx

Specimen

A. Total thyroid

B. Central cervical lymph node

Clinical Information

Thyroid cancer

Gross Description

A. Received fresh labeled "total thyroid "is a 28 g, 6.5 x 5.7 x 2.2 cm total thyroid. The specimen has a suture designating the right upper pole. The specimen is inked blue on the anterior surface and black on the posterior surface. The cut surface of the left lobe shows a 2.7 x 1.8 x 1.5 cm white-tan, ill circumscribed firm nodule. This may grossly involve the superior edge of the specimen. This comes within 0.3 cm of the isthmus. The remainder of the cut surface is pink-tan and fleshy with no other discrete gross lesions identified. Representative sections of the specimen including the entire tumor are submitted as follows: 1 - 6 entire tumor from superior to inferior including isthmus, 7 - 10 representative normal right lobe from superior to inferior. RS 10

B. Received fresh labeled "central cervical lymph node "is a 2.5 x 2.5 x 1.5 cm yellow lobular fatty tissue fragment which is bisected and entirely submitted in 2 cassettes.

ICD-O-3
carcinoma, papillary,
thyroid. 8260/3
Site: thyroid, NOS
3-9-12_{KL} C73.9

Source: NCI Genomic Data Commons file eb3b003e-1f25-46db-a1b0-42bbbbb52074 (TCGA-H2-A3RI.E9D8C054-D423-4544-97E4-0D20D78987B3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).